Somatic mutation profile of tumor specimen C3L-03728-01 (aliquot CPT0225760006) from CPTAC case C3L-03728, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.3 years (29,326 days).
Specimen C3L-03728-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed8db5e3-f5fd-4013-bd55-d979c99cb9b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03728-31 (Blood Derived Normal), aliquot CPT0226080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de17a4e1-2c46-4e0b-8254-d8b0ed3b3eae

The open-access MAF lists 82 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 19, Intron 5, Nonsense Mutation 5, Splice Site 3, 3'UTR 2, Splice Region 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1525G>C p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/525 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MARVELD2 | c.1331+1G>A p.X444_splice | Splice Site (SNP) | VAF 58/332 reads (17%) | catalogued as rs762352115, CS080713, COSV57781218; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1085308053, CM090866, COSV100909744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.7220C>T p.T2407M | Missense Mutation (SNP) | VAF 138/583 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1183274479; called by muse, mutect2, varscan2
- ANTKMT | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 79/351 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1409427063; called by muse, mutect2, varscan2
- ARAP1 | c.1016C>T p.P339L (on ENST00000393609 / NM_001040118.2; = p.P94L on NM_015242.4) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201487448; called by muse, mutect2, varscan2
- BRCA2 | c.8351G>A p.R2784Q | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs80359076, CM095253; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- CD300E | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 70/345 reads (20%) | catalogued as rs61748965; called by muse, mutect2, varscan2
- CPAMD8 | c.2521G>A p.A841T (on ENST00000651564; = p.A794T on NM_015692.5) | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770942297; called by muse, mutect2, varscan2
- CYP2A7 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151290022; called by muse, mutect2
- EPB41L4B | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1369698877; called by muse, mutect2, varscan2
- FAM162A | c.372+8G>A | Splice Region (SNP) | VAF 34/160 reads (21%) | catalogued as rs370372276; called by muse, mutect2, varscan2
- GRIA2 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52383768, COSV52408125; called by muse, mutect2, varscan2
- HIPK2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1236311429; called by muse, mutect2, varscan2
- KCNA7 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 78/507 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319506687; called by muse, mutect2, varscan2
- LCE1C | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 130/604 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs780385036, COSV64218273; called by muse, mutect2, varscan2
- MAPK9 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs780562313, COSV58119465; called by muse, mutect2, varscan2
- MDN1 | c.8410C>T p.R2804* | Nonsense Mutation (SNP) | VAF 44/219 reads (20%) | catalogued as rs149778124; called by muse, mutect2, varscan2
- MON1B | c.1446G>A p.V482= | Splice Region (SNP) | VAF 48/199 reads (24%) | catalogued as COSV99941777; called by muse, mutect2, varscan2
- MYO5C | c.2332C>T p.R778* | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | catalogued as rs754956315; called by muse, mutect2, varscan2
- NF1 | c.2702T>G p.L901* | Nonsense Mutation (SNP) | VAF 117/447 reads (26%) | catalogued as CM143350; called by muse, mutect2, varscan2
- NWD2 | c.4838G>T p.C1613F | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs1006533144; called by muse, mutect2, varscan2
- PCDHB8 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 100/973 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1274430401; called by muse, mutect2, varscan2
- PDGFRA | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 502/740 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs368266633, COSV57266911, COSV57270500, COSV57272250; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PLCE1 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as rs1482772158, COSV53357049; called by muse, mutect2, varscan2
- PLEKHN1 | c.1345C>T p.R449W (on ENST00000379409; = p.R397W on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs747891825; called by muse, mutect2, varscan2
- PP2D1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1303138313; called by muse, mutect2
- PSG6 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 67/375 reads (18%) | catalogued as rs1352818787, COSV51830330; called by muse, mutect2, varscan2
- RYR3 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374359139; called by muse, mutect2, varscan2
- SHKBP1 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 78/449 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs775771654, COSV52542439; called by muse, mutect2, varscan2
- SLC28A1 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV99722961; called by muse, mutect2, varscan2
- USH2A | c.13708C>T p.R4570C | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs141340831; called by muse, mutect2, varscan2
- VRTN | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1208336612, COSV56441774; called by muse, mutect2, varscan2
- C8orf37 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CALN1 | c.438C>A p.D146E (on ENST00000329008 / NM_001017440.3; = p.D188E on NM_031468.4) | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CCDC149 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CNKSR1 | c.917C>A p.P306Q (on ENST00000374253 / NM_001297647.2; = p.P299Q on NM_006314.3) | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEPH | c.2780T>C p.I927T (on ENST00000343002; = p.I660T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HTR5A | c.1000A>T p.N334Y | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ16 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KCTD3 | c.1310-9_1324del p.X437_splice | Splice Site (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel
- MAGEE1 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MGAT4D | c.316A>C p.K106Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10G4 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PHF21A | c.1786-1G>A p.X596_splice (on ENST00000418153 / NM_001101802.3; = p.X550_splice on NM_016621.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- PIWIL3 | c.1865T>A p.I622N | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POMGNT2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXN | c.1678G>A p.V560I (on ENST00000228307 / NM_001080855.3; = p.V526I on NM_002859.4) | Missense Mutation (SNP) | VAF 113/523 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- RAD51AP2 | c.3448A>C p.M1150L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RNF165 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TECPR2 | c.2331T>G p.S777R | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TNMD | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- USP33 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACSS1 | c.552C>T p.A184= | Silent (SNP) | VAF 104/500 reads (21%) | called by muse, mutect2, varscan2
- ATF7IP2 | c.345G>A p.S115= | Silent (SNP) | VAF 57/290 reads (20%) | catalogued as rs746450238, COSV61094790; called by muse, mutect2, varscan2
- BASP1 | c.255G>A p.A85= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1044009433, COSV100493863; called by muse, mutect2, varscan2
- CACNA1A | c.3717G>A p.L1239= | Silent (SNP) | VAF 32/260 reads (12%) | catalogued as rs369635454; called by muse, mutect2, varscan2
- CYP2B6 | c.927C>T p.Y309= | Silent (SNP) | VAF 84/448 reads (19%) | catalogued as rs768992518, COSV57842984; called by muse, mutect2, varscan2
- HSPG2 | c.8667C>T p.G2889= | Silent (SNP) | VAF 48/265 reads (18%) | catalogued as rs138583401; called by muse, mutect2, varscan2
- IFFO2 | c.1221C>T p.G407= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs760814726, COSV100841940; called by muse, mutect2, varscan2
- LAMA1 | c.5820C>T p.N1940= | Silent (SNP) | VAF 136/618 reads (22%) | catalogued as rs368850544; called by muse, mutect2, varscan2
- LONRF3 | c.1431A>T p.P477= (on ENST00000371628 / NM_001031855.3; = p.P436= on NM_024778.5) | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV59156534; called by muse, mutect2, varscan2
- LSG1 | c.1395A>G p.R465= | Silent (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- METTL2A | c.945G>A p.V315= | Silent (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- NLRP2 | c.1620C>T p.S540= | Silent (SNP) | VAF 90/452 reads (20%) | catalogued as rs190374903; called by muse, mutect2, varscan2
- OR52B2 | c.738C>T p.H246= | Silent (SNP) | VAF 78/410 reads (19%) | catalogued as COSV73209644; called by muse, mutect2, varscan2
- RELN | c.5838C>T p.I1946= | Silent (SNP) | VAF 52/295 reads (18%) | catalogued as rs759612378, COSV58994923, COSV59025189; called by muse, mutect2, varscan2
- SLX4 | c.5439C>T p.T1813= | Silent (SNP) | VAF 88/381 reads (23%) | called by muse, mutect2, varscan2
- STAT4 | c.993G>A p.P331= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as rs559315611, COSV100636189, COSV61832397; called by muse, mutect2, varscan2
- TACC3 | c.1101G>A p.L367= | Silent (SNP) | VAF 68/353 reads (19%) | catalogued as rs140424992; called by muse, mutect2, varscan2
- TGM6 | c.1425G>A p.R475= | Silent (SNP) | VAF 106/441 reads (24%) | called by muse, mutect2, varscan2
- WNT11 | c.399C>T p.G133= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as rs540581520; called by muse, varscan2
- ABCG1 | c.287-10946G>A | Intron (SNP) | VAF 65/341 reads (19%) | catalogued as rs544738327; called by muse, mutect2, varscan2
- FLT4 | c.3332-22C>T | Intron (SNP) | VAF 17/80 reads (21%) | catalogued as rs1411595264, COSV99988381; called by muse, mutect2, varscan2
- OR6W1P | n.641T>C | RNA (SNP) | VAF 60/355 reads (17%) | called by muse, mutect2, varscan2
- PXMP2 | c.519+1156G>C | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- RARA | c.*35del | 3'UTR (DEL) | VAF 69/292 reads (24%) | called by mutect2, pindel, varscan2
- REXO1L1P | chr8:85663060 T>A | 5'Flank (SNP) | VAF 85/212 reads (40%) | called by mutect2, varscan2
- SYT14 | c.*752C>T | 3'UTR (SNP) | VAF 26/111 reads (23%) | catalogued as rs1202979214; called by muse, mutect2, varscan2
- TMED10 | c.412-3279G>A | Intron (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- TMEM134 | c.452-10C>T | Intron (SNP) | VAF 56/244 reads (23%) | called by muse, varscan2
- UGT2B27P | n.1066A>G | RNA (SNP) | VAF 54/257 reads (21%) | called by muse, mutect2, varscan2
